Gene-level copy-number profile of tumor specimen 93e30fd5-e57e-4503-a175-863c7d from CPTAC case 11LU016, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 62.2 years (22,733 days).
Specimen 93e30fd5-e57e-4503-a175-863c7d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8718ef3b-f92d-4761-8da9-eff8222ee7f2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 953d4247-a33a-4caa-a0de-2f19cd (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/159a8fbe-53fe-490f-ab79-9640563f107b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 13,011; copy number 2: 37,244; copy number 3: 7,581; copy number 4: 1,070; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:84,928,353–85,011,535, 2 genes: LINC02176, ZDHHC7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:36,213,200–36,235,608, 2 genes, copy number 6: AL162511.1, RN7SKP21.

Autosomal genes at a single copy (total copy number 1): 11,303. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
